Somatic mutation profile of tumor specimen MP2PRT-PARYIZ-TMP1-A (aliquot MP2PRT-PARYIZ-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PARYIZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (731 days).
Specimen MP2PRT-PARYIZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c822579-12ff-4ba2-a210-01923a3e8cd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARYIZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARYIZ-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3951f584-c245-40ab-9c83-e9cbd8b8dcb7

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Ins 3, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BECN2 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 141/308 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.84); catalogued as COSV61560277; called by muse, mutect2
- IKZF1 | c.532delinsCC p.C178Pfs*22 | Frame Shift Ins (INS) | VAF 134/442 reads (30%) | catalogued as COSV58792112; called by mutect2*, pindel, varscan2*
- KIF26B | c.1879G>A p.V627M | Missense Mutation (SNP) | VAF 168/433 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as rs756014215; called by muse, mutect2, varscan2
- NHSL2 | c.1058C>T p.S353L (on ENST00000510661; = p.S719L on NM_001013627.2) | Missense Mutation (SNP) | VAF 99/111 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs975777771; called by muse, mutect2, varscan2
- SH3BP5 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV53743040; called by muse, mutect2, varscan2
- SNX7 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751264716; called by muse, mutect2, varscan2
- SYCE1 | c.766G>T p.A256S (on ENST00000343131 / NM_001143764.3; = p.A220S on NM_130784.3) | Missense Mutation (SNP) | VAF 11/351 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV58219504; called by muse, mutect2
- CFAP251 | c.1348_1349insCC p.S450Tfs*8 | Frame Shift Ins (INS) | VAF 28/211 reads (13%) | called by mutect2, pindel, varscan2
- IGHV1-45 | c.351_352insC | In Frame Ins (INS) | VAF 44/50 reads (88%) | called by mutect2, pindel*, varscan2
- IKZF1 | c.531dup p.C178Lfs*22 | Frame Shift Ins (INS) | VAF 116/266 reads (44%) | called by mutect2, varscan2
- KLB | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 74/329 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TULP4 | c.4534A>G p.I1512V | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2
- CFAP100 | c.225+19C>T | Intron (SNP) | VAF 155/346 reads (45%) | catalogued as rs371091744; called by muse, mutect2, varscan2
